Surgical pathology report (de-identified scan), TCGA case TCGA-L5-A4OX, project TCGA-ESCA (Esophageal Carcinoma), tissue source site University of Michigan, specimen TCGA-L5-A4OX-01A (Primary Tumor).

[page 1 of 2]
PROCEDURE: SPHS

A -year-old with esophageal cancer arising in Barrett's.

ICD-O-3

Adenocarcinoma, NOS 8140/3

Site: esophagus, distal third

C15.5

lv

10/9/12

PROCEDURE: SPGD

1. "Esophagogastrectomy". Received in formalin in a large container is a esophagogastrectomy specimen comprised of 8.5 cm long, 5 cm circumference distal esophagus with 5 cm x 12 cm circumference proximal stomach with attached perigastric adipose ranging up to 5 cm. Adventitia and serosal surface is grossly unremarkable. No perforations. Esophageal mucosa is wrinkled grey at most proximal 3 cm with a 6 cm length of salmon colored Barrett's mucosa extending to the gastroesophageal junction with a 3.3 x 2.5 cm ulcer with heaped-up borders at the gastroesophageal junction. Ulcer extends through the esophageal mucosa to a maximum depth of 1.0 cm (grossly abutting but not penetrating muscularis propria). Gastric mucosa wrinkled, tan with normal folds. No ulcers or other masses. Several lymph nodes identified in perigastric adipose tissue.

1A. Neoplasm at greatest depth and with respect to proximal.

1B. Lesion with respect to distal.

1C and D. Proximal and distal including gastroesophageal junction respectively. each).

1E. Barrett's mucosa to proximal esophagus.

1F. Barrett's mucosa to gastroesophageal junction.

1G. Multiple lymph nodes.

1H. Two lymph nodes, one inked blue. Each bisected.

1I. One grossly positive lymph node. Trisected.

1J. One grossly positive lymph node. Sectioned.

2. "Cervical esophagus margin". Received in formalin in a small container is a 1.8 cm long, 1 cm internal diameter segment of esophagus with intact adventitial lining and wrinkled grey mucosa. One stapled and open margin. Sampled at open end.

3. "Esophageal lymph node". Received in formalin in a small container is a 1.2 cm anthracotic lymph node. Bisected.

PROCEDURE: SPM1

ESOPHAGEAL, CARDIAC AND GASTROESOPHAGEAL JUNCTION CARCINOMA:

[page 2 of 2]
PREVIOUS DIAGNOSIS INQUIRY

PAGE #: 3
SEX: M

Type of carcinoma: Adenocarcinoma.

If adenocarcinoma, it is arising in: Barrett's mucosa.

Depth of invasion: Muscularis propria.

Number of positive lymph nodes: 3/15.

Extranodal metastasis: Unknown.

Pattern of invasion: Expansile.

Esophageal and gastric resection margins involved: No.

Deep resection margin involved: No.

TNM classification: T2 N1 Mx

PROCEDURE: SPDX

1. Esophagus and proximal stomach, resection: Invasive adenocarcinoma arising in Barrett's mucosa, extending focally into superficial muscularis propria. Resection margins negative. Angiolymphatic invasion present. Metastatic adenocarcinoma present in 3 of 15 lymph nodes. Incidental esophageal leiomyoma. Please see template for details.
2. Cervical esophageal margin, resection: Esophagus, negative for neoplasm.
3. Esophageal lymph node, excision: 1 lymph node, negative for neoplasm.

I, [redacted] the signing staff pathologist, have personally examined and interpreted the slides from this case.

** END OF PREVIOUS DIAGNOSIS INQUIRY **

Case is Circled		

Source: NCI Genomic Data Commons file e1c7d190-5754-4cd6-b232-aeffc02f5bd4 (TCGA-L5-A4OX.47B52FFF-17E4-4A00-ADDF-D7837E4FBAA0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).